Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A2J1, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A2J1-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

left RP LPS on imagery. No preop biopsy.

Specimens Submitted:

- 1: SP: Left retroperitoneal liposarcoma left hemicolectomy and left kidney capsule
- 2: SP: Superior aspect sigmoid colon

DIAGNOSIS:

1. RETROPERITONEUM, LEFT COLON, LEFT KIDNEY CAPSULE; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA ARISING IN WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE.
- THE DEDIFFERENTIATED COMPONENT COMPRISES APPROXIMATELY 30% OF THE OVERALL TUMOR VOLUME AND HAS A MALIGNANT FIBROUS HISTOCYTOMA-LIKE APPEARANCE.
- TUMOR HAS A BILOBED APPEARANCE, MEASURING: 31 X 20.5 X 7.5 CM.
- TUMOR INVOLVES SUBSEROSE COLONIC FAT.
- THE TUMOR EXTENDS TO UNDESIGNATED SOFT TISSUE MARGIN.
- THE WELL-DIFFERENTIATED LIPOSARCOMA EXTENDS TO THE INKED RENAL CAPSULE MARGIN.
- THE INTESTINAL RESECTION MARGINS ARE FREE OF TUMOR.
- UNREMARKABLE BOWEL AND ADRENAL GLAND.
- ONE BENIGN LYMPH NODE (0/1).
2. COLON, SIGMOID, SUPERIOR ASPECT; RESECTION:
- PORTION OF BOWEL, NO TUMOR SEEN.
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

M.D.

*** Report Electronically Signed Out ***

Gross Description:

M.D.

M.D.

** Continued on next page **

ICD-0-3

dedifferentiated liposarcoma

8858/3

Site: retroperitoneum C48.0

hw 7/24/11

[page 2 of 3]
1.) The specimen is received fresh labeled "left retroperitoneal liposarcoma, left hemicolectomy and left kidney capsule" and consists of a 49 cm long, 4.5 cm in circumference, unoriented portion of large bowel with attached mesentery measuring 46 x 20 x 4 cm and attached portion of lobulated lipomatous lesion, measuring 21 x 13 x 2 cm with a smooth membranous lining on one side, representing left kidney capsule. The membranous surface is inked black. Within the kidney capsule, a 7 x 1 x 0.8 cm disrupted adrenal gland is identified. Within the mesentery, and also with connection to the kidney capsule is a 10 x 7.5 x 5.5 cm firm nodular mass. The surface of the mass is inked black. The mass is bisected revealing a firm tan nodular cut surface. The portion of bowel appears unremarkable. No other lesions are identified grossly. Tissue is submitted for TPS, photographs are taken, and representative sections are submitted.

Summary of sections:

M1 - margin one, bowel
M2 - margin two, bowel
B - representative section, bowel
A - representative section, the adrenal
M - representative section, mesentery
C - representative section, renal capsule
T - representative section, tumor

2). The specimen is received fresh, labeled "Superior aspect sigmoid" and consists of an unoriented segment of bowel measuring 5 cm in length, with attached adipose tissue measuring 3 cm in thickness. The specimen measures 4 cm in diameter at one end and 3 cm in diameter at the other end. The specimen is open to reveal a focally hemorrhagic mucosa surface. The wall measures up to 1 cm in maximum thickness. The serosal surface is pink tan and unremarkable. No lymph nodes are identified. Representatively submitted.

Summary of sections:

E1-one end
E2-other end
RS-representative sections

Summary of Sections:

Part 1: SP: Left retroperitoneal liposarcoma left hemicolectomy and left kidney capsule

Block	Sect.	Site	PCs
1		A	1
1		B	1
10		C	10
4		M	4
1		M1	1
1		M2	1

** Continued on next page **

[page 3 of 3]
10

T

10

Part 2: SP: Superior aspect sigmoid colon

Block	Sect.	Site	PCs
1	E1		1
1	E2		1
3	RS		3

** End of Report **

Source: NCI Genomic Data Commons file 80ff98d4-1e7c-4cd2-9bb7-8c0938278a82 (TCGA-DX-A2J1.62A5DB57-875E-4825-972F-D952D985857C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).